Somatic mutation profile of tumor specimen TCGA-DJ-A3V7-01A (aliquot TCGA-DJ-A3V7-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3V7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 44.5 years (16,257 days).
Specimen TCGA-DJ-A3V7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1964adc9-0bf8-4990-ab5f-81c2f6d82102.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3V7-10A (Blood Derived Normal), aliquot TCGA-DJ-A3V7-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/128fbe11-d89c-42ac-ac2f-b452bb658f67

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRF2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as COSV55104870; called by muse, mutect2
- CFTR | c.1083G>C p.W361C | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as CD941633, COSV99140549; called by muse, mutect2
- CPT1A | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 54/143 reads (38%) | catalogued as COSV55753154; called by muse, mutect2, varscan2
- DMXL1 | c.6125G>T p.R2042L | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60705408; called by muse, mutect2, varscan2
- HSD17B3 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64556208; called by muse, mutect2, varscan2
- LMOD1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs1451879890, COSV66172069; called by muse, mutect2
- MED12L | c.5803C>T p.Q1935* | Nonsense Mutation (SNP) | VAF 6/112 reads (5%) | catalogued as COSV56369437; called by muse, mutect2
- MUC16 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV67481354, COSV67496641; called by muse, mutect2
- MYLK | c.5204G>A p.R1735Q | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60605256; called by muse, mutect2, varscan2
- PAXBP1 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as rs752646572, COSV51606942, COSV51612797; called by muse, mutect2, varscan2
- PCDHB6 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs1554277697, COSV50690241; called by muse, mutect2
- PEG3 | c.3732G>T p.M1244I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV55625666; called by muse, mutect2, varscan2
- TLR3 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.243); catalogued as COSV57167597, COSV99711186; called by muse, mutect2, varscan2
- TRIM47 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV54667574; called by muse, mutect2, varscan2
- ZG16B | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1241909776, COSV66525642; called by muse, mutect2, varscan2
- MYH1 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2
- GAK | c.690A>G p.E230= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV58502975; called by mutect2, varscan2
- MDFI | c.642G>T p.L214= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV57822548; called by muse, mutect2
- PXK | c.1440G>A p.A480= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs771832106, COSV57086780; called by muse, mutect2, varscan2
